Somatic mutation profile of tumor specimen MP2PRT-PARMXF-TMP1-A (aliquot MP2PRT-PARMXF-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARMXF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,464 days).
Specimen MP2PRT-PARMXF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e36931b7-2cc2-4762-be90-e098e3c7e79a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMXF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMXF-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d272928-a42e-4712-a65a-0032848e1fdd

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 52/756 reads (7%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2
- ADAT3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 123/898 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60190185; called by muse, mutect2, varscan2
- ARFGEF3 | c.4190G>A p.R1397H | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs547545407, COSV52449312, COSV52470397; called by muse, mutect2, varscan2
- TUB | c.178C>T p.R60W (on ENST00000299506 / NM_177972.3; = p.R115W on NM_003320.4) | Missense Mutation (SNP) | VAF 93/773 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs1415875110, COSV100210094; called by muse, mutect2, varscan2
- VCAN | c.3139C>T p.P1047S | Missense Mutation (SNP) | VAF 114/362 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV54119493; called by muse, mutect2, varscan2
- WTAP | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV61610016; called by muse, mutect2, varscan2
- CELSR3 | c.5882G>T p.C1961F | Missense Mutation (SNP) | VAF 163/493 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DYNC1H1 | c.1183G>T p.V395L | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.389); called by muse, mutect2
- PCLO | c.12078A>G p.I4026M | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- GOLGA6A | c.570G>A p.S190= | Silent (SNP) | VAF 52/558 reads (9%) | catalogued as rs1430277118; called by muse, mutect2
- MAGI2 | c.2541C>T p.H847= | Silent (SNP) | VAF 113/327 reads (35%) | catalogued as rs775086725, COSV62638497; called by muse, mutect2, varscan2
- MLPH | c.1802A>G p.*601= | Silent (SNP) | VAF 101/403 reads (25%) | called by muse, mutect2, varscan2
- PRLHR | c.516G>A p.S172= | Silent (SNP) | VAF 27/963 reads (3%) | called by muse, mutect2
- RFPL4A | c.63C>T p.A21= | Silent (SNP) | VAF 90/365 reads (25%) | catalogued as rs1045039182; called by muse, mutect2, varscan2
